Gene-level copy-number profile of specimen HCM-BROD-0001-C18-85M from HCMI case HCM-BROD-0001-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Tumor grade: GX; Age at diagnosis: 47.4 years (17,316 days).
Specimen HCM-BROD-0001-C18-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Air-Liquid Interface Organoid; Preservation method: Frozen; Passage count: 24.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 83a36b0b-5ab8-4b2e-9b1b-172fe7496c1d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0001-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,243 have no estimate.
https://portal.gdc.cancer.gov/files/1e910179-e95d-4355-964a-478276d0e147

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,443; copy number 2: 37,379; copy number 3: 12,648; copy number 4: 6,543; copy number 5: 168; copy number 6: 117; copy number 7: 30; copy number 8: 24; copy number 9: 26; copy number 10: 1; copy number 12: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 346 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–145,739,288, 76 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:199,752,491–200,177,420, 9 genes, copy number 5–6: AL596266.1, AL445687.1, RNU6-778P, AL445687.2, RNU6-716P, RNU6-609P, NR5A2, RNU6-570P, AC096633.1.
- chr2:72,175,984–74,217,565, 48 genes, copy number 6 (within-gene range 4–6): EXOC6B, RPS15AP13, RNU2-39P, AC092630.1, SPR, EMX1, AC012366.1, SFXN5, RAB11FIP5, AC010913.1, NOTO, SMYD5, PRADC1, CCT7, FBXO41, EGR4, RNU6-111P, AC074008.2, RPSAP28, ALMS1, ALMS1-IT1, AC074008.1, NAT8, ALMS1P1, NAT8B, TPRKB, AC092653.1, AC092653.2, DUSP11, C2orf78, STAMBP, AC073046.3, AC073046.2, ACTG2, DGUOK, DGUOK-AS1, RNA5SP97, AC073046.1, TET3, AC110801.1, FNBP1P1, AC073263.1, BOLA3, BOLA3-AS1, MOB1A, MTHFD2, AC073263.3, AC073263.2.
- chr2:74,834,127–74,893,359, 1 gene, copy number 5: HK2.
- chr2:88,811,186–88,825,207, 2 genes, copy number 6: MALLP2, MIR4436A.
- chr8:42,541,155–43,085,788, 15 genes, copy number 7 (within-gene range 3–7): SMIM19, CHRNB3, AC103843.1, AC103843.2, CHRNA6, THAP1, AC087533.1, RNF170, RN7SL806P, MIR4469, HOOK3, Y_RNA, AC110275.1, FNTA, RNU1-124P.
- chr8:102,528,740–102,539,943, 2 genes, copy number 5: AP002852.1, RNU6-1224P.
- chr8:105,546,089–106,060,524, 3 genes, copy number 5 (within-gene range 4–5): ZFPM2-AS1, AC103853.1, AC103853.2.
- chr8:105,826,570–108,083,642, 18 genes, copy number 5: AC090802.1, Y_RNA, SLC16A14P1, AC027031.1, AC027031.2, OXR1, AC090579.1, TAGLN2P1, RNU7-84P, ABRA, AP003789.1, HMGB1P46, ANGPT1, PGAM1P13, AC025508.1, RNA5SP275, RSPO2, NRBF2P4.
- chr8:108,871,128–120,373,573, 92 genes, copy number 5–10 (broad region; genes not listed).
- chr8:124,044,395–124,728,473, 16 genes, copy number 5 (within-gene range 4–5): FER1L6-AS2, AC100871.1, ARF1P3, AC090921.1, RNU6-756P, AC090192.2, AC090192.1, TMEM65, TRMT12, RNF139-AS1, RNF139, TATDN1, AC090198.1, MIR6844, NDUFB9, MTSS1.
- chr9:61,190,003–61,662,690, 11 genes, copy number 6: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1.
- chr10:75,397,830–76,560,168, 11 genes, copy number 6 (within-gene range 2–6): ZNF503, ZNF503-AS2, AC010997.5, AC010997.4, AC010997.2, LRMDA, AC010997.6, MIR606, AL589863.2, AL589863.1, AL731568.1.
- chr10:125,473,686–126,421,879, 24 genes, copy number 7–8: RPS27P18, TEX36-AS1, TEX36, ALDOAP2, AL158835.1, EDRF1-DT, AL158835.3, AL158835.2, EDRF1, EDRF1-AS1, MMP21, UROS, MIR4484, BCCIP, DHX32, Metazoa_SRP, RNU2-42P, FANK1, GNG10P1, FANK1-AS1, ADAM12, RNA5SP328, SAR1AP2, LINC00601.
- chr14:18,333,726–18,341,859, 1 gene, copy number 5: CR383658.1.
- chr14:18,601,045–18,637,421, 6 genes, copy number 5–7: OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.1, CR383656.12.
- chr15:30,420,283–30,420,429, 1 gene, copy number 12: AC019322.2.
- chr15:30,540,093–30,545,969, 1 gene, copy number 8: AC026150.1.
- chr18:22,164,886–22,419,294, 9 genes, copy number 5: GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1.

Autosomal genes at a single copy (total copy number 1): 541. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
